Gene-level copy-number profile of tumor specimen C3N-01902-05 from CPTAC case C3N-01902, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.0 years (23,391 days).
Specimen C3N-01902-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01666116-919d-4f16-b540-20e1d4182f80.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01902-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/95c3c42e-c7ac-4328-9550-3b971435b67e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 485; copy number 1: 7,224; copy number 2: 48,856; copy number 3: 2,329; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:12,104,389–12,177,550, 7 genes (within-gene range 0–1): ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
